Somatic mutation profile of tumor specimen TCGA-78-7145-01A (aliquot TCGA-78-7145-01A-11D-2036-08) from TCGA case TCGA-78-7145, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 52.2 years (19,080 days).
Specimen TCGA-78-7145-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c37fc808-f63e-40a5-9892-40a3d2d68c2f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-78-7145-10A (Blood Derived Normal), aliquot TCGA-78-7145-10A-01D-2036-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/652f3ee5-c653-4596-aeee-28984b11c5ae

The open-access MAF lists 202 somatic variants for this specimen: 152 protein-altering or splice-affecting, 47 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 128, Silent 47, Nonsense Mutation 13, Frame Shift Del 5, Splice Site 4, Splice Region 2, Intron 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 14/24 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 14/24 reads (58%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.475G>C p.A159P | Missense Mutation (SNP) | VAF 26/42 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs730882000, COSV52661847, COSV52680639, COSV52688008, COSV52782769; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACSBG2 | c.1582C>A p.P528T | Missense Mutation (SNP) | VAF 62/90 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53122891; called by muse, mutect2, varscan2
- ADAMTS12 | c.3763C>A p.H1255N | Missense Mutation (SNP) | VAF 85/170 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as rs922399712, COSV100711466, COSV61255312; called by muse, mutect2, varscan2
- ADAMTS3 | c.3569A>C p.K1190T | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.399); catalogued as COSV54384455; called by muse, mutect2, varscan2
- ADCY9 | c.954G>T p.M318I | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.78); catalogued as COSV53571422, COSV53576348; called by muse, mutect2, varscan2
- ADGRE2 | c.1471G>T p.G491* | Nonsense Mutation (SNP) | VAF 39/57 reads (68%) | catalogued as COSV59691622; called by muse, mutect2, varscan2
- ADGRL2 | c.752A>T p.H251L | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54651767; called by muse, mutect2, varscan2
- AMER1 | c.2620G>T p.G874* | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as COSV57654726; called by muse, mutect2, varscan2
- ANO1 | c.997G>C p.A333P | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV60281097; called by muse, mutect2, varscan2
- ARID1B | c.4232C>T p.P1411L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs1258284323, COSV51648316; called by muse, mutect2, varscan2
- ATRNL1 | c.3500G>T p.G1167V | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV58073609; called by muse, mutect2
- BCORL1 | c.4755A>T p.Q1585H | Missense Mutation (SNP) | VAF 65/186 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV54389378, COSV99501420; called by muse, mutect2, varscan2
- C22orf42 | c.569T>C p.L190P | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.883); catalogued as COSV66075204; called by muse, mutect2, varscan2
- CABS1 | c.862G>T p.D288Y | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV56732910; called by muse, mutect2, varscan2
- CACNA2D1 | c.2725G>T p.A909S (on ENST00000356253 / NM_001366867.1; = p.A897S on NM_000722.4) | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV62372224; called by muse, mutect2, varscan2
- CAMTA1 | c.1369C>T p.P457S | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.003); catalogued as COSV57881431; called by muse, mutect2, varscan2
- CCDC62 | c.498G>T p.K166N | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53430699; called by muse, mutect2, varscan2
- CD84 | c.658C>A p.R220S | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.18); catalogued as COSV60866754, COSV60868005; called by muse, mutect2, varscan2
- CDH10 | c.1409C>T p.T470I | Missense Mutation (SNP) | VAF 39/64 reads (61%) | SIFT tolerated (0.96); PolyPhen benign (0.007); catalogued as rs145457868; called by muse, mutect2, varscan2
- CENPU | c.941A>T p.E314V | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV55656401; called by muse, mutect2, varscan2
- CFAP54 | c.4845A>T p.K1615N | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.787); catalogued as rs1368264308, COSV61570469; called by muse, mutect2, varscan2
- CHRNA6 | c.805G>A p.G269S | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52378490; called by muse, mutect2, varscan2
- CHRNB3 | c.671C>A p.T224K | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV51493106; called by muse, mutect2, varscan2
- CHST4 | c.901C>T p.H301Y | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV58296454; called by muse, mutect2, varscan2
- CMTM7 | c.523G>T p.V175F | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV58549814, COSV58552353; called by muse, mutect2, varscan2
- COL6A3 | c.7764G>A p.L2588= | Splice Region (SNP) | VAF 5/27 reads (19%) | catalogued as rs1407366621, COSV55079517; called by muse, mutect2, varscan2
- COL6A5 | c.6119T>A p.L2040Q (on ENST00000312481; = p.L2036Q on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.472); catalogued as COSV55193460; called by muse, mutect2, varscan2
- CRISPLD1 | c.360G>T p.L120F | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51544131; called by muse, mutect2, varscan2
- CSMD3 | c.290C>G p.A97G | Missense Mutation (SNP) | VAF 70/151 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV52100372; called by muse, mutect2, varscan2
- CYCS | c.4G>C p.G2R | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV59872402; called by muse, mutect2, varscan2
- DCST2 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs200996276, COSV99791688; called by muse, mutect2, varscan2
- DDIT4 | c.472C>T p.H158Y | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.932); catalogued as COSV56577113; called by muse, mutect2, varscan2
- DGKI | c.2878T>A p.C960S | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.044); catalogued as COSV55935930; called by muse, mutect2, varscan2
- DMD | c.2861G>T p.W954L | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.013); catalogued as COSV63734363, COSV63743115; called by muse, mutect2, varscan2
- DSP | c.1538C>A p.P513H | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65791040; called by muse, mutect2, varscan2
- EGFL6 | c.113C>A p.P38H | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV63632797; called by muse, mutect2, varscan2
- EMX2 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.09); catalogued as rs1426142917, COSV71294387, COSV71294478; called by muse, mutect2, varscan2
- EPB41L4A | c.686G>T p.G229V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54862405; called by muse, mutect2, varscan2
- ERMAP | c.1267G>T p.V423F | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.36); catalogued as rs765133970, COSV60273423; called by muse, mutect2, varscan2
- FAM189A2 | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as COSV57383573; called by muse, mutect2, varscan2
- FAM83B | c.1580A>G p.E527G | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV60919231; called by muse, mutect2, varscan2
- FOLH1 | c.547G>T p.E183* | Nonsense Mutation (SNP) | VAF 9/61 reads (15%) | catalogued as COSV57045475, COSV99923286, COSV99923733; called by muse, mutect2, varscan2
- FYN | c.1509G>T p.W503C | Missense Mutation (SNP) | VAF 64/167 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57609608; called by muse, mutect2
- GALNTL6 | c.1505G>A p.W502* | Nonsense Mutation (SNP) | VAF 35/80 reads (44%) | catalogued as rs868183409, COSV72489249; called by muse, mutect2, varscan2
- GATA1 | c.883C>A p.L295M | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV100936733; called by muse, mutect2, varscan2
- GCAT | c.869G>C p.R290P | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50648642; called by muse, mutect2, varscan2
- GGCX | c.2038C>T p.R680* | Nonsense Mutation (SNP) | VAF 47/110 reads (43%) | catalogued as COSV52087073; called by muse, mutect2, varscan2
- GIMAP6 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.042); catalogued as rs865805939, COSV61032437; called by muse, mutect2
- GK | c.367G>T p.V123F | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66735498; called by muse, mutect2, varscan2
- GK | c.568G>T p.V190F | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.353); catalogued as COSV66735507; called by muse, mutect2, varscan2
- GLI2 | c.679C>A p.L227M | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.961); catalogued as COSV58034411; called by muse, mutect2, varscan2
- GPRASP2 | c.1220G>C p.C407S | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV59990254; called by muse, mutect2, varscan2
- GRB14 | c.1325A>G p.H442R | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV55735632; called by muse, mutect2, varscan2
- HNRNPH2 | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 19/103 reads (18%) | catalogued as COSV54508075; called by muse, mutect2, varscan2
- HPS6 | c.1759G>A p.A587T | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.974); catalogued as COSV54624870; called by muse, mutect2, varscan2
- HRH2 | c.892G>A p.G298R | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as rs749245496, COSV51572695, COSV51572738; called by muse, mutect2, varscan2
- IQUB | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as COSV61236767; called by muse, mutect2, varscan2
- KCNB2 | c.477G>T p.M159I | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1563525577, COSV73048847; called by muse, mutect2, varscan2
- KCNH2 | c.2351G>T p.R784L | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV51126208; called by muse, mutect2, varscan2
- KIAA1210 | c.556C>A p.Q186K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.414); catalogued as COSV68175398; called by muse, mutect2, varscan2
- LAMB4 | c.800G>T p.C267F | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52713159; called by muse, mutect2, varscan2
- LAMC3 | c.1383-1G>T p.X461_splice | Splice Site (SNP) | VAF 14/54 reads (26%) | catalogued as COSV63088523; called by muse, mutect2, varscan2
- LCA5 | c.427C>G p.Q143E | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as COSV63970487; called by muse, mutect2
- LPAR1 | c.968G>C p.R323T | Missense Mutation (SNP) | VAF 55/81 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV62687024, COSV62688799; called by muse, mutect2, varscan2
- LRP1B | c.11845A>G p.K3949E | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.024); catalogued as COSV101255051, COSV67185367; called by muse, varscan2
- LRP1B | c.11791C>G p.Q3931E | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.081); catalogued as COSV67185373, COSV67186115; called by muse, varscan2
- LRRC7 | c.586G>C p.G196R (on ENST00000651989 / NM_001370785.2; = p.G163R on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50410222; called by muse, mutect2, varscan2
- LRRTM3 | c.1658C>A p.T553K | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as rs761729350, COSV63661281, COSV63670443; called by muse, mutect2, varscan2
- MAGEB16 | c.750C>G p.I250M | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV67873534; called by muse, mutect2, varscan2
- MAGI2 | c.2152C>T p.P718S | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV62633309; called by muse, mutect2, varscan2
- MAP2K7 | c.727G>T p.D243Y | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67607577, COSV67607584; called by muse, mutect2, varscan2
- MAP7D2 | c.1161G>C p.L387F | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.602); catalogued as COSV65525552; called by muse, mutect2, varscan2
- MARK1 | c.1534G>A p.D512N | Missense Mutation (SNP) | VAF 63/136 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV65065462; called by muse, mutect2, varscan2
- MMAA | c.52A>G p.R18G | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); catalogued as COSV55579024; called by muse, mutect2, varscan2
- MRM1 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.109); catalogued as rs767540749; called by muse, mutect2, varscan2
- MTMR8 | c.482A>G p.Y161C | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV66392279; called by muse, mutect2, varscan2
- MUC16 | c.4784C>A p.T1595K | Missense Mutation (SNP) | VAF 71/112 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as COSV67444071; called by muse, mutect2, varscan2
- NCSTN | c.1300C>G p.R434G | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as rs1085307081, CM123788, COSV54184491, COSV54192064; called by muse, mutect2, varscan2
- NDRG4 | c.104C>A p.T35N (on ENST00000570248 / NM_001378344.1; = p.T67N on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50746338; called by muse, mutect2, varscan2
- NFKBIZ | c.1765A>G p.K589E | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.74); catalogued as COSV58199308; called by muse, mutect2, varscan2
- NKTR | c.4200-2A>T p.X1400_splice | Splice Site (SNP) | VAF 12/32 reads (38%) | catalogued as COSV51769282; called by muse, mutect2, varscan2
- NNT | c.2899G>T p.G967C | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52922492; called by muse, mutect2, varscan2
- OR2T3 | c.858C>G p.F286L | Missense Mutation (SNP) | VAF 68/368 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV62081695; called by muse, mutect2, varscan2
- OR4C13 | c.161G>T p.R54I | Missense Mutation (SNP) | VAF 58/173 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV73648617, COSV73648851; called by muse, mutect2, varscan2
- OR4C6 | c.663C>A p.C221* | Nonsense Mutation (SNP) | VAF 30/88 reads (34%) | catalogued as rs773479464, COSV58602488, COSV58604890; called by muse, mutect2, varscan2
- OR4F6 | c.631T>C p.F211L | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.651); catalogued as COSV61026274; called by muse, mutect2, varscan2
- OR4X1 | c.703C>A p.L235I | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60722211, COSV60722944; called by muse, mutect2, varscan2
- OR51I2 | c.210T>A p.D70E | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as COSV58297865; called by muse, mutect2, varscan2
- OR52L1 | c.985G>T p.D329Y | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as COSV59986591; called by muse, mutect2, varscan2
- OR52L1 | c.984G>T p.K328N | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV100176076; called by muse, mutect2, varscan2
- OR52N1 | c.298C>A p.L100I | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57692903; called by muse, mutect2, varscan2
- OR8D2 | c.791C>A p.S264Y | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV62488021; called by muse, mutect2, varscan2
- ORC1 | c.222T>C p.D74= | Splice Region (SNP) | VAF 17/132 reads (13%) | catalogued as COSV57121672; called by muse, mutect2, varscan2
- OTOP1 | c.447C>A p.C149* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as rs746564651, COSV56390624; called by muse, mutect2, varscan2
- OVCH2 | c.470T>A p.F157Y | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (1); PolyPhen possibly damaging (0.791); catalogued as COSV71952635; called by muse, mutect2, varscan2
- PANX1 | c.1201+1G>T p.X401_splice | Splice Site (SNP) | VAF 4/24 reads (17%) | catalogued as rs1284018027, COSV57132668; called by muse, mutect2
- PCDHA13 | c.2171C>T p.S724L | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.055); catalogued as rs1554181562, COSV56477143; called by muse, mutect2, varscan2
- PCDHGA4 | c.1549C>T p.R517* | Nonsense Mutation (SNP) | VAF 38/154 reads (25%) | catalogued as rs1197287768, COSV53897391, COSV53982497; called by muse, mutect2, varscan2
- PDZRN4 | c.2740C>A p.R914S (on ENST00000402685 / NM_001164595.2; = p.R656S on NM_013377.4) | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54191734; called by muse, mutect2, varscan2
- PHYHIPL | c.532G>A p.G178R | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.975); catalogued as COSV65847647; called by muse, mutect2, varscan2
- PIK3CB | c.632G>T p.S211I | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.544); catalogued as COSV56683327; called by mutect2, varscan2
- PRDM2 | c.1999C>G p.L667V | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.435); catalogued as COSV52442770, COSV52446122; called by muse, mutect2, varscan2
- PROKR2 | c.425C>A p.S142Y | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54085161, COSV54087171; called by muse, mutect2, varscan2
- RIF1 | c.149A>T p.E50V | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.085); catalogued as COSV54612262; called by muse, mutect2, varscan2
- RNMT | c.644G>A p.W215* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as COSV51084041; called by muse, mutect2, varscan2
- S1PR1 | c.425G>T p.R142L | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59512524; called by muse, mutect2, varscan2
- SH3PXD2B | c.2236C>T p.P746S | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.037); catalogued as COSV61124653; called by muse, mutect2, varscan2
- SIX2 | c.823C>A p.Q275K | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as COSV57389999; called by muse, mutect2, varscan2
- SLC26A2 | c.667A>C p.S223R | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.239); catalogued as COSV53824301; called by muse, mutect2, varscan2
- SLC49A3 | c.811G>T p.E271* (on ENST00000404286 / NM_001294341.2; = p.E270* on NM_032219.4) | Nonsense Mutation (SNP) | VAF 56/124 reads (45%) | catalogued as COSV59139337; called by muse, mutect2, varscan2
- SLC8A3 | c.1723G>T p.G575C | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63518902; called by muse, mutect2, varscan2
- SLC9A6 | c.988A>G p.T330A | Missense Mutation (SNP) | VAF 82/235 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as COSV65787249; called by muse, mutect2, varscan2
- SLCO6A1 | c.51G>T p.R17S | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV65805503, COSV65808512; called by muse, mutect2, varscan2
- SLITRK2 | c.1867C>G p.L623V | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59422998, COSV59426717; called by muse, mutect2, varscan2
- SPATA2 | c.1030A>T p.R344W | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as COSV56865405; called by muse, mutect2, varscan2
- STAB2 | c.936G>C p.Q312H | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV66333959; called by muse, mutect2, varscan2
- STRN | c.413-1G>T p.X138_splice | Splice Site (SNP) | VAF 12/65 reads (18%) | catalogued as COSV55745758; called by muse, mutect2, varscan2
- STS | c.616G>A p.V206M | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); catalogued as rs775526497, COSV54265732, COSV54271752; called by muse, mutect2, varscan2
- STXBP6 | c.223G>T p.V75F | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.083); catalogued as COSV60589867; called by muse, mutect2, varscan2
- SYT9 | c.1379A>T p.N460I | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as COSV59614588; called by muse, mutect2, varscan2
- TAAR8 | c.478C>T p.L160F | Missense Mutation (SNP) | VAF 111/238 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV51585578; called by muse, mutect2, varscan2
- TAF1 | c.3635G>T p.R1212M (on ENST00000373790 / NM_138923.4; = p.R1233M on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99334957; called by muse, mutect2, varscan2
- TAF1L | c.946G>T p.A316S | Missense Mutation (SNP) | VAF 33/53 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as rs1347187300, COSV54257988; called by muse, mutect2, varscan2
- TBX5 | c.1417C>A p.Q473K | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as COSV59858399, COSV59861423; called by muse, mutect2, varscan2
- TFAP2D | c.1085C>A p.S362Y | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as COSV50408287; called by muse, mutect2, varscan2
- TIAM2 | c.1674G>T p.M558I | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV100018283; called by muse, mutect2, varscan2
- TIAM2 | c.1675G>T p.D559Y | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100018289; called by muse, mutect2, varscan2
- TLR2 | c.1393A>T p.S465C | Missense Mutation (SNP) | VAF 36/63 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52604909; called by muse, mutect2, varscan2
- TMTC3 | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99898188; called by muse, mutect2, varscan2
- TRPM6 | c.2618G>T p.W873L | Missense Mutation (SNP) | VAF 40/53 reads (75%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV62502738, COSV62511103; called by muse, mutect2, varscan2
- TTC3 | c.4224G>T p.E1408D | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV61285773; called by muse, varscan2
- TTC8 | c.1447C>T p.P483S (on ENST00000338104 / NM_001288781.1; = p.P467S on NM_144596.4) | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs759772798, COSV57626061; called by muse, mutect2, varscan2
- TTK | c.1725G>C p.L575F | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57881429; called by muse, mutect2, varscan2
- TTN | c.33205C>T p.P11069S (on ENST00000591111; = p.P10142S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/113 reads (21%) | PolyPhen benign (0.007); catalogued as rs1382172649, COSV59883219; called by muse, mutect2, varscan2
- TUT4 | c.3268G>T p.A1090S | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV57109876; called by muse, mutect2, varscan2
- USO1 | c.2012A>T p.Q671L | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV53704977; called by muse, mutect2, varscan2
- USP31 | c.2704G>T p.A902S | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.083); catalogued as COSV54849225; called by muse, mutect2, varscan2
- USP40 | c.1627G>T p.A543S | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52477182; called by muse, mutect2, varscan2
- ZNF648 | c.608C>A p.T203K | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0.096); catalogued as COSV60569637; called by muse, mutect2, varscan2
- ZNF678 | c.1457A>G p.E486G | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.633); catalogued as COSV59380087; called by muse, mutect2, varscan2
- ZNF816 | c.502C>T p.H168Y | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as COSV54410376, COSV54412506; called by muse, mutect2, varscan2
- ZNF85 | c.409T>C p.C137R | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV56020952; called by muse, mutect2, varscan2
- AKAP9 | c.3148del p.V1050Wfs*10 | Frame Shift Del (DEL) | VAF 19/52 reads (37%) | called by mutect2, pindel, varscan2
- CNR1 | c.1023del p.A342Pfs*6 | Frame Shift Del (DEL) | VAF 24/105 reads (23%) | called by mutect2, pindel, varscan2
- CNTN3 | c.1339del p.D447Mfs*2 | Frame Shift Del (DEL) | VAF 16/84 reads (19%) | called by mutect2, pindel, varscan2
- FRG2C | c.689C>A p.T230N | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.978); called by muse, mutect2
- IGHV3-48 | c.237C>A p.Y79* | Nonsense Mutation (SNP) | VAF 22/202 reads (11%) | called by muse, varscan2
- PHAX | c.974G>T p.R325M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- TMEM79 | c.563del p.G188Afs*11 | Frame Shift Del (DEL) | VAF 35/125 reads (28%) | called by mutect2, pindel, varscan2
- ZNF318 | c.6055del p.D2019Ifs*11 | Frame Shift Del (DEL) | VAF 35/103 reads (34%) | called by mutect2, pindel, varscan2
- ARHGAP36 | c.6T>C p.G2= | Silent (SNP) | VAF 37/88 reads (42%) | catalogued as COSV52263739; called by muse, mutect2, varscan2
- ASXL1 | c.2094G>T p.P698= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV60102984, COSV60112150; called by muse, mutect2, varscan2
- BTBD11 | c.1485G>C p.V495= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV55016731; called by muse, mutect2, varscan2
- CCKBR | c.360C>T p.F120= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV58098544; called by muse, mutect2
- CDH12 | c.57C>T p.L19= | Silent (SNP) | VAF 34/280 reads (12%) | catalogued as COSV66387594; called by muse, mutect2, varscan2
- CDKN2C | c.48G>A p.G16= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV99395764; called by muse, mutect2, varscan2
- CHKA | c.390T>A p.P130= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV55838412; called by muse, mutect2, varscan2
- CNTN3 | c.432C>T p.C144= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs200292687, COSV55162412; called by muse, mutect2, varscan2
- CNTNAP2 | c.1416C>T p.L472= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV62144240; called by muse, mutect2, varscan2
- CPT1B | c.339C>T p.S113= | Silent (SNP) | VAF 50/108 reads (46%) | catalogued as COSV56414963; called by muse, mutect2, varscan2
- CSF1R | c.1521G>T p.T507= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV53828281, COSV99643172; called by muse, mutect2, varscan2
- DISP2 | c.291G>A p.R97= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as COSV51116436; called by muse, mutect2, varscan2
- DSP | c.4230G>A p.K1410= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as COSV65791045; called by muse, mutect2, varscan2
- DUSP7 | c.597G>T p.S199= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV56588588; called by muse, mutect2, varscan2
- EGFL6 | c.558C>A p.P186= | Silent (SNP) | VAF 36/106 reads (34%) | catalogued as COSV63632807; called by muse, mutect2, varscan2
- FCGBP | c.9570C>T p.C3190= | Silent (SNP) | VAF 22/111 reads (20%) | catalogued as rs751103208; called by muse, mutect2, varscan2
- FHL5 | c.793C>T p.L265= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs566257304, COSV58735135; called by muse, mutect2, varscan2
- FOXO1 | c.774C>T p.D258= | Silent (SNP) | VAF 52/84 reads (62%) | catalogued as COSV65425097; called by muse, mutect2, varscan2
- GRHL3 | c.117G>A p.P39= (on ENST00000350501 / NM_198174.3; = p.P44= on NM_021180.3) | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as rs142785065; called by muse, mutect2, varscan2
- IGKV1D-16 | c.36C>A p.L12= | Silent (SNP) | VAF 52/178 reads (29%) | called by muse, mutect2, varscan2
- ITIH6 | c.318C>A p.I106= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as COSV54486371; called by muse, mutect2, varscan2
- KATNIP | c.4641C>T p.T1547= | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as rs764503597, COSV55173278; called by muse, mutect2
- KEL | c.771G>T p.L257= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as COSV62333179; called by muse, mutect2, varscan2
- MC5R | c.756C>A p.A252= | Silent (SNP) | VAF 27/123 reads (22%) | catalogued as COSV61253879; called by muse, mutect2, varscan2
- MUC16 | c.22227C>G p.S7409= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV67444063, COSV67480979; called by muse, mutect2
- NEUROG2 | c.57G>T p.L19= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs771673824, COSV57636803; called by muse, mutect2, varscan2
- NOA1 | c.678G>C p.L226= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV51735873; called by muse, mutect2, varscan2
- NR2E1 | c.783C>A p.I261= | Silent (SNP) | VAF 24/104 reads (23%) | catalogued as COSV64561351, COSV64561680; called by muse, mutect2, varscan2
- OCRL | c.2412T>C p.C804= | Silent (SNP) | VAF 39/100 reads (39%) | catalogued as COSV63980072; called by muse, mutect2, varscan2
- OPN1LW | c.6C>G p.A2= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV100886864; called by muse, mutect2, varscan2
- OR4X1 | c.165C>T p.S55= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as rs539642827, COSV60722204; called by muse, mutect2, varscan2
- OTC | c.726C>A p.T242= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as COSV50000177; called by muse, mutect2, varscan2
- PGBD4 | c.801G>A p.P267= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs755332934, COSV56626444; called by muse, mutect2, varscan2
- PTPRN | c.2073G>T p.T691= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as COSV55345526; called by muse, mutect2, varscan2
- RNF32 | c.526C>A p.R176= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as COSV58731150; called by muse, mutect2, varscan2
- SLC24A4 | c.609G>T p.V203= | Silent (SNP) | VAF 31/79 reads (39%) | catalogued as COSV54106922; called by muse, mutect2, varscan2
- SLC25A53 | c.102G>T p.G34= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV62458309; called by muse, mutect2, varscan2
- SLITRK2 | c.720G>A p.E240= | Silent (SNP) | VAF 43/134 reads (32%) | catalogued as COSV59422987; called by muse, mutect2, varscan2
- STAB2 | c.1776C>A p.V592= | Silent (SNP) | VAF 89/286 reads (31%) | catalogued as COSV66333967; called by muse, mutect2, varscan2
- TEX14 | c.276T>A p.P92= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV53611643; called by muse, mutect2, varscan2
- THEM5 | c.657C>A p.I219= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as COSV64312686; called by muse, mutect2, varscan2
- TRPM4 | c.1140C>G p.A380= | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as COSV53260114; called by muse, mutect2, varscan2
- TTN | c.80073T>C p.A26691= (on ENST00000591111; = p.A19267= on NM_003319.4) | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as COSV59883196; called by muse, mutect2, varscan2
- VWF | c.4683C>A p.I1561= | Silent (SNP) | VAF 20/31 reads (65%) | catalogued as rs750219929, COSV54611286; called by muse, mutect2, varscan2
- WDPCP | c.831G>T p.L277= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV55412753; called by muse, mutect2, varscan2
- ZBTB24 | c.1933C>T p.L645= | Silent (SNP) | VAF 33/69 reads (48%) | catalogued as COSV57781190; called by muse, mutect2, varscan2
- ZFYVE9 | c.3645C>T p.Y1215= | Silent (SNP) | VAF 30/90 reads (33%) | catalogued as COSV55089955; called by muse, mutect2, varscan2
- AQR | c.471+1091G>C | Intron (SNP) | VAF 70/111 reads (63%) | catalogued as COSV50038873; called by muse, mutect2, varscan2
- FAM27E5 | n.356C>A | RNA (SNP) | VAF 29/89 reads (33%) | catalogued as rs755322487; called by muse, mutect2, varscan2
- RPGR | c.2520+220G>T | Intron (SNP) | VAF 10/32 reads (31%) | catalogued as COSV58832381; called by muse, mutect2
